Somatic mutation profile of tumor specimen C3L-05325-54 (aliquot CPT0302970002) from CPTAC case C3L-05325, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 87.0 years (31,782 days).
Specimen C3L-05325-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 834b5fd7-f963-435d-8477-a19ac0b94886.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05325-51 (Buccal Cell Normal), aliquot CPT0303090001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a57ae47b-513c-468b-91e5-6d1debcb9a32

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.383dup p.P129Afs*41 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | catalogued as COSV57200888; called by mutect2, pindel, varscan2
- SMC3 | c.2535+1G>A p.X845_splice | Splice Site (SNP) | VAF 12/201 reads (6%) | catalogued as COSV62420100; called by muse, mutect2
